Gene-level copy-number profile of tumor specimen TCGA-4Z-AA82-01A from TCGA case TCGA-4Z-AA82, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.9 years (21,893 days).
Specimen TCGA-4Z-AA82-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6af97cd8-1eac-4285-aec5-0ef020fe6990.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA82-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26669f26-1068-4909-a39b-bebfb56d8a96

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 209; copy number 2: 3,439; copy number 3: 18,906; copy number 4: 26,674; copy number 5: 3,143; copy number 6: 5,064; copy number 7: 2,030; copy number 8: 31; copy number 9: 185; copy number 10: 75; copy number 11: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA82-01A-11D-A390-01): tumor purity 0.58, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 309 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,713,877–41,043,890, 174 genes, copy number 9–10 (broad region; genes not listed).
- chr1:41,098,638–41,099,136, 1 gene, copy number 10: RPL23AP17.
- chr1:235,131,634–237,833,988, 53 genes, copy number 9 (within-gene range 6–9): ARID4B, MIR4753, RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, AL122018.2, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2, MTR, RPSAP21, RPL35P1, MT1HL1, AL359259.1, RYR2, RN7SKP195, MIR4428, AL442065.1.
- chr7:17,299,295–17,558,909, 4 genes, copy number 10: AC019117.3, SNORA63, AC019117.2, AC019117.1.
- chr8:100,157,906–100,259,278, 1 gene, copy number 11 (within-gene range 6–11): SPAG1.
- chr8:100,185,138–101,669,726, 47 genes, copy number 11: Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr8:101,686,547–101,689,093, 1 gene, copy number 11: AP000426.1.
- chr9:110,303,476–111,996,739, 28 genes, copy number 9 (within-gene range 6–9): TXNDC8, SVEP1, RNU6-1039P, AL592463.1, MUSK, AL513328.1, LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668, RNU6-710P.

Autosomal genes at a single copy (total copy number 1): 209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
